Somatic mutation profile of tumor specimen TCGA-5P-A9JU-01A (aliquot TCGA-5P-A9JU-01A-11D-A42J-10) from TCGA case TCGA-5P-A9JU, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 81.0 years (29,594 days).
Specimen TCGA-5P-A9JU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecce0dce-7be6-4b5b-aed1-40e30850d943.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5P-A9JU-10A (Blood Derived Normal), aliquot TCGA-5P-A9JU-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59feac14-350a-4572-a2cd-40ffa3216f7f

The open-access MAF lists 85 somatic variants for this specimen: 68 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 14, Frame Shift Del 11, Nonsense Mutation 3, Splice Site 3, Frame Shift Ins 3, In Frame Ins 2, In Frame Del 2, RNA 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCB1 | c.983G>A p.R328Q (on ENST00000263121; = p.R374Q on NM_003073.5) | Missense Mutation (SNP) | VAF 43/62 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs1057517825, CM1311945, COSV51954334, COSV51955761; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABL2 | c.2034G>T p.Q678H (on ENST00000502732 / NM_007314.4; = p.Q663H on NM_005158.5) | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.028); catalogued as COSV100772991; called by muse, mutect2, varscan2
- AKAP13 | c.1340A>C p.Q447P | Missense Mutation (SNP) | VAF 94/206 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100774655; called by muse, mutect2
- BCAM | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs577903824, COSV99538977; called by muse, mutect2, varscan2
- BCKDK | c.424-1G>T p.X142_splice | Splice Site (SNP) | VAF 30/75 reads (40%) | catalogued as COSV99570870; called by muse, mutect2, varscan2
- CDC42BPG | c.2455C>T p.R819W | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs765608758, COSV100712157; called by muse, mutect2, varscan2
- CYP2A13 | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100387021, COSV57840255; called by muse, mutect2
- DSCC1 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100558413; called by muse, mutect2, varscan2
- ESCO1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs1413696338, COSV99332588; called by muse, mutect2, varscan2
- FAM89A | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs147790876, COSV100792569, COSV64166120; called by muse, mutect2, varscan2
- FAM91A1 | c.1561-1G>A p.X521_splice | Splice Site (SNP) | VAF 16/60 reads (27%) | catalogued as COSV100593794; called by muse, mutect2, varscan2
- FGFRL1 | c.914T>A p.V305E | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99294850; called by muse, mutect2, varscan2
- GLMN | c.1597T>A p.S533T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.315); catalogued as COSV100950198; called by muse, mutect2, varscan2
- GRN | c.526A>C p.T176P | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as COSV99275113; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1703C>A p.P568Q | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99647603; called by muse, mutect2, varscan2
- INTS8 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100569474; called by muse, mutect2, varscan2
- IRF7 | c.800C>T p.T267M (on ENST00000397566; = p.T254M on NM_001572.5) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs571836045, COSV99213450; called by muse, mutect2, varscan2
- ITGA5 | c.2890C>G p.L964V | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.199); catalogued as COSV99516951; called by muse, mutect2, varscan2
- MUC5AC | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); catalogued as COSV100650692; called by muse, mutect2, varscan2
- MYO9A | c.3238C>G p.L1080V | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV100614296; called by muse, mutect2, varscan2
- NBAS | c.3214G>C p.A1072P | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99871576; called by muse, mutect2, varscan2
- NFIC | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100545645; called by muse, mutect2
- NT5C1A | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs572504200, COSV99348684; called by muse, mutect2, varscan2
- NUF2 | c.1225A>C p.K409Q | Missense Mutation (SNP) | VAF 40/560 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99616972; called by muse, mutect2
- OR51B4 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 85/197 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV66517004; called by muse, mutect2, varscan2
- PTGDS | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as COSV99812063; called by muse, mutect2, varscan2
- RABL6 | c.245G>T p.S82I | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100273739; called by muse, mutect2, varscan2
- RBBP6 | c.1645T>C p.S549P | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100154958; called by muse, mutect2, varscan2
- RIPK3 | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99353464; called by muse, mutect2, varscan2
- RNF216 | c.168_170del p.E57del | In Frame Del (DEL) | VAF 16/92 reads (17%) | catalogued as rs1562462440; called by pindel, varscan2
- SCNN1A | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs865917379, COSV99964949; called by muse, mutect2, varscan2
- SLC28A1 | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1050112789, COSV99723535; called by muse, mutect2, varscan2
- SRR | c.792G>T p.E264D | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.203); catalogued as COSV100027222; called by muse, mutect2, varscan2
- SYT16 | c.104T>A p.L35* | Nonsense Mutation (SNP) | VAF 42/129 reads (33%) | catalogued as COSV101413685; called by muse, mutect2, varscan2
- SYT16 | c.105A>T p.L35F | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.026); catalogued as rs761390939, COSV101413686; called by muse, mutect2, varscan2
- TBC1D23 | c.1413+1G>A p.X471_splice | Splice Site (SNP) | VAF 48/62 reads (77%) | catalogued as COSV61370489; called by muse, mutect2, varscan2
- TIMM8B | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.675); catalogued as COSV99736667; called by muse, mutect2, varscan2
- TNRC18 | c.4366T>G p.Y1456D | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV101269881; called by muse, mutect2
- TRIP6 | c.877G>C p.V293L | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV99566883; called by muse, mutect2, varscan2
- TRMT1L | c.1477G>T p.E493* | Nonsense Mutation (SNP) | VAF 25/79 reads (32%) | catalogued as COSV100834752; called by muse, mutect2, varscan2
- TTC17 | c.2687G>A p.R896H | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as rs150211914; called by muse, mutect2, varscan2
- TTC21B | c.500A>G p.Y167C | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs1416735161, COSV99692866; called by muse, mutect2, varscan2
- USP29 | c.940C>A p.L314I | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99518653; called by muse, mutect2, varscan2
- USP29 | c.941T>A p.L314H | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99518654; called by muse, mutect2, varscan2
- USP34 | c.9143A>G p.N3048S | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.931); catalogued as COSV101277213; called by muse, mutect2, varscan2
- USP34 | c.9142A>T p.N3048Y | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV101277214; called by muse, mutect2, varscan2
- VN1R1 | c.656T>C p.L219S | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100320771; called by muse, mutect2, varscan2
- WWTR1 | c.250C>G p.H84D | Missense Mutation (SNP) | VAF 57/72 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100640965; called by muse, mutect2, varscan2
- ZNF248 | c.1533A>C p.Q511H | Missense Mutation (SNP) | VAF 39/53 reads (74%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.745); catalogued as COSV100627741; called by muse, mutect2, varscan2
- ZNF341 | c.1933G>A p.E645K (on ENST00000375200 / NM_001282935.1; = p.E638K on NM_032819.4) | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.727); catalogued as rs1247018390, COSV100678056; called by muse, mutect2, varscan2
- ZNF594 | c.2289T>A p.C763* | Nonsense Mutation (SNP) | VAF 33/91 reads (36%) | catalogued as COSV101280578; called by muse, mutect2, varscan2
- ABCG1 | c.424del p.A142Pfs*37 | Frame Shift Del (DEL) | VAF 31/86 reads (36%) | called by mutect2, pindel, varscan2
- AP2A1 | c.1982_2002del p.L661_P667del | In Frame Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel, varscan2
- ASAP2 | c.110_111del p.V37Gfs*35 | Frame Shift Del (DEL) | VAF 19/92 reads (21%) | called by pindel, varscan2
- ATP7B | c.3255dup p.E1086Rfs*32 | Frame Shift Ins (INS) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- CACNA1S | c.5161_5164del p.M1721* | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- CASC3 | c.231+2_231+3del | Frame Shift Del (DEL) | VAF 30/88 reads (34%) | called by pindel, varscan2
- FAM172A | c.746del p.N249Tfs*8 | Frame Shift Del (DEL) | VAF 32/92 reads (35%) | called by mutect2, pindel, varscan2
- PCCB | c.193dup p.T65Nfs*17 | Frame Shift Ins (INS) | VAF 46/122 reads (38%) | called by mutect2, pindel, varscan2
- PLEKHO2 | c.1131del p.W378Gfs*39 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by mutect2, pindel, varscan2
- POLR1G | c.301del p.A101Qfs*15 | Frame Shift Del (DEL) | VAF 27/70 reads (39%) | called by mutect2, pindel, varscan2
- PTDSS2 | c.233_239del p.Y78Cfs*52 | Frame Shift Del (DEL) | VAF 40/115 reads (35%) | called by mutect2, pindel, varscan2
- SETD2 | c.3234del p.L1078Ffs*43 | Frame Shift Del (DEL) | VAF 37/57 reads (65%) | called by mutect2, pindel, varscan2
- SLC12A7 | c.144_146dup p.E48_N49insK | In Frame Ins (INS) | VAF 33/76 reads (43%) | called by mutect2, pindel, varscan2
- TRPM1 | c.2402_2403del p.K801Rfs*3 | Frame Shift Del (DEL) | VAF 25/88 reads (28%) | called by mutect2, pindel, varscan2
- UBE3B | c.2462del p.S821Ffs*25 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- ZNF141 | c.1204_1205insCAA p.G401_K402insT | In Frame Ins (INS) | VAF 109/263 reads (41%) | called by mutect2, pindel, varscan2
- ZNF77 | c.213dup p.V72Cfs*7 | Frame Shift Ins (INS) | VAF 29/83 reads (35%) | called by mutect2, pindel, varscan2
- ADNP | c.1086A>G p.Q362= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs1267484832, COSV62424907; called by muse, mutect2, varscan2
- AHNAK2 | c.13551C>T p.S4517= | Silent (SNP) | VAF 51/110 reads (46%) | catalogued as rs574414313, COSV100318924; called by muse, mutect2, varscan2
- CCAR1 | c.3429C>G p.S1143= | Silent (SNP) | VAF 223/341 reads (65%) | catalogued as COSV99771413; called by muse, mutect2, varscan2
- CYP2A13 | c.429C>T p.R143= | Silent (SNP) | VAF 20/172 reads (12%) | catalogued as rs780349763, COSV57836519; called by muse, mutect2
- DUOXA1 | c.906C>T p.L302= | Silent (SNP) | VAF 52/122 reads (43%) | catalogued as COSV99973550; called by muse, mutect2, varscan2
- GPR26 | c.975C>T p.G325= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs758121720, COSV52937076; called by muse, mutect2, varscan2
- MROH6 | c.531G>A p.L177= | Silent (SNP) | VAF 58/186 reads (31%) | catalogued as COSV99435571; called by muse, mutect2, varscan2
- PADI6 | c.1359T>C p.S453= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100640022; called by muse, mutect2, varscan2
- PIKFYVE | c.714T>C p.D238= | Silent (SNP) | VAF 40/89 reads (45%) | catalogued as COSV100011449; called by muse, mutect2, varscan2
- TGFBR3 | c.1632G>A p.E544= | Silent (SNP) | VAF 87/201 reads (43%) | catalogued as COSV53025598, COSV99283672; called by muse, mutect2, varscan2
- TMC5 | c.1230T>A p.I410= (on ENST00000396229 / NM_001105248.1; = p.I164= on NM_024780.5) | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV99572860; called by muse, mutect2, varscan2
- VPS39 | c.1950T>C p.A650= (on ENST00000348544 / NM_001301138.2; = p.A639= on NM_015289.5) | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV100529586; called by muse, mutect2, varscan2
- VSIG4 | c.333C>T p.Y111= | Silent (SNP) | VAF 98/124 reads (79%) | catalogued as COSV101038316; called by muse, mutect2, varscan2
- WNK1 | c.5598A>G p.A1866= (on ENST00000315939 / NM_018979.4; = p.A1618= on NM_014823.3) | Silent (SNP) | VAF 55/141 reads (39%) | catalogued as COSV60041464; called by muse, mutect2, varscan2
- ITLN2 | c.-2G>C | 5'UTR (SNP) | VAF 57/126 reads (45%) | catalogued as COSV100600744, COSV100600759; called by muse, mutect2, varscan2
- MIR99AHG | n.607A>C | RNA (SNP) | VAF 88/260 reads (34%) | called by muse, mutect2, varscan2
- SSPOP | n.986A>G | RNA (SNP) | VAF 59/130 reads (45%) | catalogued as rs767772426, COSV100022993; called by muse, mutect2, varscan2
